Somatic mutation profile of tumor specimen TCGA-B5-A11U-01A (aliquot TCGA-B5-A11U-01A-11D-A122-09) from TCGA case TCGA-B5-A11U, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 74.4 years (27,160 days).
Specimen TCGA-B5-A11U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 982c16d1-86a5-4e4d-a790-23ac36289863.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11U-10A (Blood Derived Normal), aliquot TCGA-B5-A11U-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0b6b4b4-866b-4072-85ad-50360bf6c773

The open-access MAF lists 459 somatic variants for this specimen: 342 protein-altering or splice-affecting, 109 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 203, Silent 109, Frame Shift Del 92, Frame Shift Ins 23, Nonsense Mutation 13, In Frame Del 6, Splice Site 4, Intron 4, RNA 2, 5'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH7A1 | c.1093+1G>A p.X365_splice | Splice Site (SNP) | VAF 24/264 reads (9%) | catalogued as rs794727058, CS106148, COSV63160839; ClinVar: pathogenic; called by muse, mutect2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 58/154 reads (38%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CASK | c.2485C>T p.Q829* (on ENST00000378163 / NM_001367721.1; = p.Q824* on NM_003688.3) | Nonsense Mutation (SNP) | VAF 119/320 reads (37%) | catalogued as rs587783364, COSV59364432; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.377del p.P126Rfs*89 | Frame Shift Del (DEL) | VAF 42/118 reads (36%) | catalogued as rs1060501215; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COX14 | c.81del p.Y28Tfs*83 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs34028295, COSV58724413; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 61/157 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.4130del p.P1377Lfs*2 | Frame Shift Del (DEL) | VAF 141/438 reads (32%) | catalogued as rs34678453; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DICER1 | c.4031C>T p.S1344L | Missense Mutation (SNP) | VAF 45/111 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58615689; called by muse, mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by pindel, varscan2
- KMT2D | c.1940dup p.P648Tfs*2 | Frame Shift Ins (INS) | VAF 27/103 reads (26%) | catalogued as rs770315135; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PNPLA2 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918259, CM070243, COSV60744000; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 74/268 reads (28%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- ADGRE2 | c.1936C>T p.L646F | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV59692715; called by muse, mutect2, varscan2
- ADRA1B | c.1026C>A p.C342* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV60701208; called by muse, mutect2, varscan2
- AGO2 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV55046481, COSV55050813; called by muse, mutect2, varscan2
- AIP | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs752553438, COSV54160273; called by muse, mutect2
- AKAP13 | c.3833T>C p.M1278T | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.006); catalogued as rs980974981, COSV63453016; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 52/126 reads (41%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKT1S1 | c.495del p.T166Pfs*87 (on ENST00000344175 / NM_001098633.4; = p.T186Pfs*87 on NM_032375.5) | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | catalogued as rs748776119, COSV59276444; called by mutect2, pindel, varscan2
- ALKBH8 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 143/389 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52834332; called by muse, mutect2, varscan2
- AMBRA1 | c.2225G>A p.R742H (on ENST00000458649 / NM_001367468.1; = p.R652H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs753438290, COSV54051560; called by muse, mutect2, varscan2
- ANKRD35 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.997); catalogued as COSV100841651; called by muse, mutect2
- AP002748.5 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 8/122 reads (7%) | catalogued as COSV100567741; called by muse, mutect2
- AP3S2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 97/267 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs781619946, COSV100318405, COSV60518876; called by muse, mutect2, varscan2
- APOH | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 141/411 reads (34%) | catalogued as rs150681833, COSV52771433; called by muse, mutect2, varscan2
- APP | c.945G>C p.K315N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV60996831; called by muse, mutect2, varscan2
- ARHGAP22 | c.1334del p.G445Afs*18 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs748723326; called by mutect2, varscan2
- ARHGAP33 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.91); catalogued as rs202132781, COSV50119830; called by muse, mutect2, varscan2
- ARHGAP33 | c.2372C>A p.P791H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99137664; called by muse, mutect2, varscan2
- ARHGEF40 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757893683, COSV53879341; called by muse, mutect2, varscan2
- ARID5B | c.3368C>T p.S1123L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV99689192; called by muse, mutect2
- ARSI | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60817132; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 168/460 reads (37%) | catalogued as rs753865255; called by mutect2, varscan2
- ATM | c.8082_8084del p.G2695del | In Frame Del (DEL) | VAF 102/307 reads (33%) | catalogued as rs1565540828; called by pindel, varscan2
- ATP2C1 | c.1592C>A p.P531H | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV60754707, COSV60754877; called by muse, mutect2, varscan2
- BBS12 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 121/341 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs200240034, COSV58561755; called by muse, mutect2, varscan2
- BCL11B | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs757442289, COSV100595247; called by mutect2, varscan2
- BCORL1 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs1420562958, COSV54388958, COSV99499855; called by muse, mutect2, varscan2
- BRD4 | c.3842G>A p.R1281Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs199802230, COSV54584523; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 20/161 reads (12%) | catalogued as rs752512017; called by mutect2, varscan2
- C1QTNF3 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1185713060, COSV51467683; called by muse, mutect2, varscan2
- C1orf50 | c.418T>C p.W140R | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV65308166; called by muse, mutect2, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 73/439 reads (17%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CA5B | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759792043, COSV59416086; called by muse, mutect2, varscan2
- CACNA1E | c.1916A>T p.N639I | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100701431; called by muse, mutect2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPZA3 | c.296dup p.N99Kfs*15 | Frame Shift Ins (INS) | VAF 64/200 reads (32%) | catalogued as rs1322309653; called by mutect2, pindel, varscan2
- CCL21 | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs749355595, COSV52398737; called by muse, mutect2, varscan2
- CD163 | c.1427G>T p.R476M | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as COSV63131091; called by muse, mutect2, varscan2
- CD207 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs781869546, COSV69651945; called by muse, mutect2, varscan2
- CEBPZ | c.1428dup p.D477Rfs*3 | Frame Shift Ins (INS) | VAF 67/198 reads (34%) | catalogued as rs763090473; called by mutect2, varscan2
- CEP192 | c.2362del p.T788Qfs*40 | Frame Shift Del (DEL) | VAF 79/226 reads (35%) | catalogued as COSV58068098; called by mutect2, pindel, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 44/119 reads (37%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHRFAM7A | c.589T>C p.S197P | Missense Mutation (SNP) | VAF 146/620 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55397165; called by muse, mutect2, varscan2
- CHRNA6 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52379096; called by muse, mutect2, varscan2
- CIC | c.3347dup p.S1117Kfs*34 | Frame Shift Ins (INS) | VAF 25/64 reads (39%) | catalogued as rs761345552; called by mutect2, varscan2
- CIDEB | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs368449983; called by muse, mutect2, varscan2
- CKAP4 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1305051841, COSV65172295; called by muse, mutect2, varscan2
- CLASP2 | c.1079A>T p.Q360L | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV56279553; called by muse, mutect2, varscan2
- CNEP1R1 | c.293G>A p.R98Q (on ENST00000427478 / NM_001281789.1; = p.R115Q on NM_153261.5) | Missense Mutation (SNP) | VAF 176/540 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as rs1339172158, COSV66696799; called by muse, mutect2, varscan2
- CNTN1 | c.2600G>A p.R867K | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV61638324; called by muse, mutect2, varscan2
- COL6A2 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs146742517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A1 | c.2677G>T p.G893* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV57881750; called by muse, mutect2, varscan2
- CRAMP1 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 32/73 reads (44%) | catalogued as COSV51960911; called by muse, mutect2, varscan2
- CRTAM | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as rs1265633376, COSV57067299; called by muse, mutect2, varscan2
- CRYAB | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782520163, COSV57051556; called by muse, mutect2, varscan2
- CSDE1 | c.2194G>C p.A732P (on ENST00000358528 / NM_001007553.3; = p.A701P on NM_007158.6) | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV54741601, COSV54743063; called by muse, mutect2, varscan2
- CSMD1 | c.9811T>C p.C3271R (on ENST00000520002; = p.C3270R on NM_033225.6) | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100144942; called by muse, mutect2
- CSNK1G2 | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs765618157, COSV55336766; called by muse, mutect2, varscan2
- CTNNA2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as rs1245962200, COSV63557850; called by muse, mutect2, varscan2
- CUL9 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV52727297; called by muse, mutect2, varscan2
- CWC22 | c.2380C>T p.R794* | Nonsense Mutation (SNP) | VAF 56/630 reads (9%) | catalogued as rs1175103916, COSV55430552; called by muse, mutect2
- CYP27A1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.366); catalogued as COSV51467555; called by muse, varscan2
- CYP2E1 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1425889399, COSV53313109, COSV99428836; called by muse, mutect2
- DDX59 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV100494438; called by muse, mutect2
- DLAT | c.342del p.E115Rfs*10 | Frame Shift Del (DEL) | VAF 108/264 reads (41%) | catalogued as rs782180715; called by mutect2, varscan2
- DNAH7 | c.5947del p.S1983Vfs*9 | Frame Shift Del (DEL) | VAF 155/453 reads (34%) | catalogued as rs745449105; called by mutect2, pindel, varscan2
- DNMT3A | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53046433; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 96/218 reads (44%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.5450T>C p.L1817S | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1450419343, COSV70235287; called by muse, mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 75/515 reads (15%) | catalogued as rs748134881; called by mutect2, varscan2
- DOP1A | c.6274C>T p.Q2092* | Nonsense Mutation (SNP) | VAF 281/698 reads (40%) | catalogued as COSV52708702; called by muse, mutect2, varscan2
- DPH7 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 14/196 reads (7%) | catalogued as rs1564428205, COSV53023896, COSV99483395; called by muse, mutect2
- DUSP14 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs751469260; called by muse, mutect2, varscan2
- DUSP16 | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 150/445 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV53807108; called by muse, mutect2, varscan2
- E2F3 | c.148_159del p.A50_A53del | In Frame Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs759216279; called by mutect2, varscan2
- EDIL3 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 136/416 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as rs1292758330, COSV56890191; called by muse, mutect2, varscan2
- EPPK1 | c.5030G>A p.G1677D | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73260687; called by muse, mutect2, varscan2
- FAF1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 156/403 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65637578; called by muse, mutect2, varscan2
- FAHD2B | c.842dup p.G282Rfs*17 | Frame Shift Ins (INS) | VAF 58/182 reads (32%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM199X | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.634); catalogued as COSV100245528; called by muse, mutect2
- FAT3 | c.12475G>A p.A4159T | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.976); catalogued as rs1452177328, COSV53095080; called by muse, mutect2, varscan2
- FBXL2 | c.730T>C p.C244R | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52137910; called by muse, mutect2, varscan2
- FBXW10 | c.506-2A>G p.X169_splice | Splice Site (SNP) | VAF 153/449 reads (34%) | catalogued as rs773189502, COSV57316103; called by muse, mutect2, varscan2
- FBXW10 | c.1513A>G p.K505E | Missense Mutation (SNP) | VAF 62/671 reads (9%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.995); catalogued as COSV57316110; called by muse, mutect2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as rs768979093, COSV55110370; called by pindel, varscan2
- FLNC | c.5996G>A p.R1999Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as rs1346364708, COSV57953622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNDC3B | c.3165dup p.T1056Hfs*16 | Frame Shift Ins (INS) | VAF 68/220 reads (31%) | catalogued as rs769012096; called by mutect2, varscan2
- FNDC4 | c.30del p.S11Afs*17 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs771665646, COSV99253963; called by mutect2, varscan2
- FUT4 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62469161; called by muse, mutect2, varscan2
- GABRB2 | c.1456G>A p.A486T (on ENST00000274547; = p.A448T on NM_000813.3) | Missense Mutation (SNP) | VAF 136/389 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.113); catalogued as COSV50906373; called by muse, mutect2, varscan2
- GCC1 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV58462186; called by muse, mutect2, varscan2
- GLI3 | c.2107T>C p.S703P | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.146); catalogued as COSV67887106; called by muse, mutect2, varscan2
- GMCL1 | c.842del p.K281Sfs*15 | Frame Shift Del (DEL) | VAF 117/357 reads (33%) | catalogued as rs1558541290; called by mutect2, pindel, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 62/196 reads (32%) | catalogued as rs752075537; called by mutect2, varscan2
- GPKOW | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV50242365; called by muse, mutect2, varscan2
- GPR158 | c.2949del p.T984Pfs*7 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | catalogued as rs974932436; called by mutect2, pindel, varscan2
- GRIP2 | c.1012G>A p.A338T (on ENST00000619221; = p.A241T on NM_001080423.4) | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV56120769; called by muse, mutect2, varscan2
- GSTZ1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV53623219; called by muse, mutect2, varscan2
- H2BC5 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.304); catalogued as COSV56800547; called by muse, mutect2, varscan2
- HCAR2 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.23); catalogued as COSV61024690; called by muse, mutect2, varscan2
- HCFC1 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60071161; called by muse, mutect2, varscan2
- HGSNAT | c.133del p.R45Dfs*5 | Frame Shift Del (DEL) | VAF 70/242 reads (29%) | catalogued as rs1220771600; called by pindel, varscan2
- HIBCH | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 103/305 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV62891234; called by muse, mutect2, varscan2
- HNRNPF | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV61560841; called by muse, mutect2, varscan2
- HNRNPL | c.1432A>G p.S478G | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs751146495, COSV99670074; called by muse, mutect2
- HNRNPUL1 | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1038497639, COSV54561419; called by muse, mutect2, varscan2
- HOXA7 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.242); catalogued as rs766259696, COSV54217160; called by muse, mutect2, varscan2
- HRH1 | c.787A>G p.K263E | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.197); catalogued as COSV67955287; called by muse, mutect2, varscan2
- HSF5 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV100050837; called by muse, mutect2
- HSPBP1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as rs1395993205, COSV55333903; called by muse, mutect2, varscan2
- IBTK | c.1673A>C p.D558A | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV60392069; called by muse, mutect2, varscan2
- IGFALS | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs754902130, COSV51905321; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL3RA | c.572T>C p.F191S | Missense Mutation (SNP) | VAF 114/354 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.036); catalogued as COSV58430617; called by muse, mutect2, varscan2
- IL6R | c.1129G>T p.G377* | Nonsense Mutation (SNP) | VAF 131/325 reads (40%) | catalogued as COSV59816022; called by muse, mutect2, varscan2
- INPP5D | c.1843C>A p.L615M (on ENST00000445964 / NM_001017915.3; = p.L614M on NM_005541.5) | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV64036402; called by muse, mutect2, varscan2
- ITPR3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777019225, COSV65407660; called by muse, mutect2, varscan2
- ITPRID2 | c.3136G>A p.A1046T | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs774758622, COSV57470705; called by muse, mutect2, varscan2
- ITSN1 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV66082349; called by muse, mutect2, varscan2
- KALRN | c.4472G>A p.R1491Q | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53759192, COSV53759495; called by muse, mutect2, varscan2
- KCNA5 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52903904; called by muse, mutect2, varscan2
- KCNH3 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.748); catalogued as COSV57790240; called by muse, mutect2, varscan2
- KCTD19 | c.2301del p.V768Wfs*38 | Frame Shift Del (DEL) | VAF 13/112 reads (12%) | catalogued as rs759860142; called by mutect2, pindel, varscan2
- KIF13A | c.1235A>T p.E412V | Missense Mutation (SNP) | VAF 250/755 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99434494; called by muse, mutect2
- KRT25 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56444354; called by muse, mutect2, varscan2
- KRT80 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs552916758, COSV57548421; called by muse, mutect2, varscan2
- LDB3 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV99554835; called by muse, mutect2
- LDHB | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV63364527; called by muse, mutect2, varscan2
- LGALS3BP | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs776549166, COSV53164511, COSV53164591; called by muse, mutect2, varscan2
- LMCD1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.539); catalogued as rs774235968, COSV50087771; called by muse, mutect2, varscan2
- LRP2 | c.11729G>T p.G3910V | Missense Mutation (SNP) | VAF 223/583 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55548169; called by muse, mutect2, varscan2
- LRRC8C | c.1601C>T p.T534I | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs150400983, COSV64996659; called by muse, mutect2, varscan2
- MAP1B | c.5901dup p.E1968Rfs*8 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | catalogued as rs775893760; called by mutect2, varscan2
- MBP | c.835G>A p.D279N (on ENST00000355994 / NM_001025101.2; = p.D161N on NM_002385.3) | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as rs1337832380, COSV62828920; called by muse, mutect2, varscan2
- MC4R | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55351712; called by muse, mutect2, varscan2
- MDH1B | c.923T>C p.V308A | Missense Mutation (SNP) | VAF 132/394 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV65589115; called by muse, mutect2, varscan2
- MDN1 | c.6335G>A p.R2112Q | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs143104857; called by muse, mutect2, varscan2
- MEGF6 | c.4318dup p.A1440Gfs*4 | Frame Shift Ins (INS) | VAF 14/24 reads (58%) | catalogued as rs759225724; called by mutect2, varscan2
- MICAL3 | c.4495dup p.R1499Pfs*26 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs765803753; called by mutect2, varscan2
- MPP2 | c.432del p.S145Afs*33 (on ENST00000461854 / NM_001278372.2; = p.S121Afs*33 on NM_005374.5) | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as rs748468544; called by mutect2, pindel, varscan2
- MPPED2 | c.62A>C p.N21T | Missense Mutation (SNP) | VAF 232/550 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV63897361; called by muse, varscan2
- MSMO1 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 42/564 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99823269, COSV99823305; called by muse, mutect2
- MSRB1 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 90/222 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1212344280, COSV51906051, COSV51906717; called by muse, mutect2, varscan2
- MUC21 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.047); catalogued as rs371928221; called by muse, mutect2
- MXRA5 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 87/277 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54230762; called by muse, mutect2, varscan2
- MYF6 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57351174; called by muse, mutect2, varscan2
- MYO16 | c.3169del p.Y1057Tfs*15 | Frame Shift Del (DEL) | VAF 115/353 reads (33%) | catalogued as rs1451313099; called by mutect2, pindel, varscan2
- NBEA | c.5734C>T p.R1912C | Missense Mutation (SNP) | VAF 111/353 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1166864537, COSV59757369; called by muse, mutect2, varscan2
- NBEAL2 | c.4144C>T p.P1382S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as COSV52756278; called by muse, mutect2, varscan2
- NEURL4 | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.05); catalogued as rs775286254, COSV59757777; called by muse, mutect2
- NEXMIF | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV50025917, COSV50047393; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as COSV53499514; called by mutect2, pindel, varscan2
- NINL | c.1337G>T p.R446M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54000679; called by muse, mutect2, varscan2
- NIPBL | c.8134G>A p.A2712T | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV56948120; called by muse, mutect2, varscan2
- NLGN4X | c.1079G>A p.G360D | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as COSV52011924; called by muse, mutect2, varscan2
- NPR2 | c.1654C>T p.H552Y | Missense Mutation (SNP) | VAF 71/561 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.036); catalogued as COSV61310047; called by muse, mutect2, varscan2
- NR4A2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59893306; called by muse, mutect2, varscan2
- NTNG1 | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53962679; called by muse, mutect2, varscan2
- NUDT22 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54171890; called by muse, mutect2
- OR4K2 | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 199/544 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV53848920; called by muse, mutect2, varscan2
- OR5A2 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57390730; called by muse, mutect2, varscan2
- OR5D18 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 16/337 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1488665846, COSV61736999; called by muse, mutect2
- OR5T3 | c.742A>G p.K248E | Missense Mutation (SNP) | VAF 156/421 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57380059; called by muse, mutect2, varscan2
- OTUD4 | c.2795C>T p.P932L (on ENST00000447906 / NM_001366057.1; = p.P867L on NM_001102653.1) | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs762042941, COSV71381723; called by muse, mutect2, varscan2
- PALLD | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV54977312; called by muse, mutect2, varscan2
- PAM | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs376009666; called by muse, mutect2, varscan2
- PARP15 | c.998C>T p.S333L (on ENST00000464300 / NM_001113523.3; = p.S99L on NM_152615.2) | Missense Mutation (SNP) | VAF 102/305 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV59972110; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 64/226 reads (28%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCDH1 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs572369161, COSV99745643; called by muse, mutect2
- PCDH19 | c.1613G>A p.G538D | Missense Mutation (SNP) | VAF 88/230 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV55256904; called by muse, mutect2, varscan2
- PCDHGA6 | c.1107del p.Q370Kfs*9 | Frame Shift Del (DEL) | VAF 23/157 reads (15%) | catalogued as COSV53946532; called by mutect2, pindel, varscan2
- PDK1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs982748518, COSV56374878; called by muse, mutect2, varscan2
- PDS5A | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57824404; called by muse, mutect2, varscan2
- PGK2 | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 196/463 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867271999, COSV59163408; called by muse, mutect2, varscan2
- PHF3 | c.1889C>A p.P630H | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.58); catalogued as COSV50315987; called by muse, mutect2, varscan2
- PIBF1 | c.33del p.V12* | Frame Shift Del (DEL) | VAF 53/153 reads (35%) | catalogued as rs925772654; called by mutect2, pindel, varscan2
- PIWIL1 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.19); catalogued as COSV55345577; called by muse, mutect2, varscan2
- PKD1 | c.12325C>T p.R4109C (on ENST00000262304 / NM_001009944.3; = p.R4108C on NM_000296.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs750666594, COSV51913745; called by muse, mutect2, varscan2
- PKD2L1 | c.1880+2T>G p.X627_splice | Splice Site (SNP) | VAF 79/280 reads (28%) | catalogued as COSV58395407; called by muse, mutect2, varscan2
- PLEKHA4 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99612201; called by muse, mutect2
- POLR1G | c.653del p.N218Ifs*4 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs753626854; called by mutect2, varscan2
- POLR3E | c.1782dup p.G595Rfs*39 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs777556882; called by mutect2, varscan2
- POU4F1 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); catalogued as rs925126425, COSV65884041; called by muse, mutect2, varscan2
- PPARD | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1279571584, COSV61099326; called by muse, mutect2, varscan2
- PPP1R13B | c.1149C>T p.S383= | Splice Region (SNP) | VAF 22/66 reads (33%) | catalogued as rs761350958, COSV52450347; called by muse, mutect2, varscan2
- PPP1R3A | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52879841; called by muse, mutect2, varscan2
- PSPC1 | c.1417T>G p.S473A | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as COSV58887531; called by muse, varscan2
- PTH | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 137/345 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.219); catalogued as COSV56378335; called by muse, mutect2, varscan2
- PTPRB | c.52T>G p.S18A | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.079); catalogued as rs1190631411, COSV51728793; called by muse, mutect2, varscan2
- PTPRK | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 133/340 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV63894701; called by muse, mutect2, varscan2
- PTTG1 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs1261407879, COSV61677866; called by muse, mutect2, varscan2
- PYHIN1 | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 163/444 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.13); catalogued as COSV63730465; called by muse, mutect2, varscan2
- RAD54L | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV100914759, COSV64336197; called by muse, mutect2
- RANBP6 | c.2983_2984del p.V995Kfs*4 | Frame Shift Del (DEL) | VAF 130/429 reads (30%) | catalogued as rs777752468; called by pindel, varscan2
- RBM15B | c.2529del p.S844Pfs*27 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | catalogued as rs781825075; called by mutect2, pindel, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 80/218 reads (37%) | catalogued as rs762006287; called by mutect2, varscan2
- RBPJL | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.15); catalogued as rs764004793, COSV59213197; called by muse, mutect2, varscan2
- REV3L | c.9128C>A p.P3043H | Missense Mutation (SNP) | VAF 129/333 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV62617530; called by muse, mutect2, varscan2
- RGR | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as rs773435796, COSV63893762; called by muse, mutect2, varscan2
- RHOA | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 321/812 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as COSV69042166; called by muse, mutect2, varscan2
- RIMBP2 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs368697814; called by muse, mutect2, varscan2
- RNF10 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV58044392; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs755128667, COSV68457540; called by pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 122/176 reads (69%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD2 | c.4076G>T p.G1359V | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV64819281; called by muse, mutect2, varscan2
- RPUSD2 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV59765171; called by muse, mutect2, varscan2
- RYR3 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs745418555, COSV66781899; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SAPCD2 | c.712_714del p.E238del | In Frame Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs755834020; called by mutect2, pindel, varscan2
- SEC16A | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs777294928, COSV51523649; called by muse, mutect2, varscan2
- SERPINA6 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs766474893, COSV58585813, COSV58586331; called by muse, mutect2
- SGO2 | c.3783-1G>A p.X1261_splice | Splice Site (SNP) | VAF 218/636 reads (34%) | catalogued as rs1337505237, COSV63414725; called by muse, mutect2, varscan2
- SHC3 | c.848dup p.L283Ffs*5 | Frame Shift Ins (INS) | VAF 25/81 reads (31%) | catalogued as rs869116869; called by mutect2, pindel, varscan2
- SLC16A7 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 94/293 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.386); catalogued as rs150567250; called by muse, mutect2, varscan2
- SLC17A6 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV54135078; called by muse, mutect2, varscan2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 79/197 reads (40%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC26A9 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61601880; called by muse, mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 22/144 reads (15%) | catalogued as rs753589038, COSV53507811; called by mutect2, varscan2
- SLC7A14 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 201/471 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51580132; called by muse, mutect2, varscan2
- SMARCE1 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 151/412 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs140414666; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMPD4 | c.2413G>T p.G805C (on ENST00000409031 / NM_017951.4; = p.G776C on NM_017751.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV60079466; called by muse, mutect2, varscan2
- SNTA1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369968387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX14 | c.1725del p.F575Lfs*53 (on ENST00000314673 / NM_001350535.1; = p.F522Lfs*53 on NM_020468.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 99/305 reads (32%) | catalogued as rs1311909367; called by mutect2, pindel, varscan2
- SNX19 | c.2216C>T p.T739I | Missense Mutation (SNP) | VAF 13/405 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV99772886; called by muse, mutect2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 38/93 reads (41%) | catalogued as rs750890082; called by mutect2, varscan2
- SPNS2 | c.1576_1578del p.F526del | In Frame Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs764334781; called by pindel, varscan2
- SPTAN1 | c.2372G>T p.R791L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV63986332; called by muse, mutect2, varscan2
- SREBF2 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.181); catalogued as rs764977781, COSV63330908; called by muse, mutect2, varscan2
- SREK1IP1 | c.381del p.K129Nfs*29 | Frame Shift Del (DEL) | VAF 42/147 reads (29%) | catalogued as rs1470980144, COSV72486131; called by mutect2, pindel, varscan2
- SRF | c.1073A>G p.Q358R | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV54838215; called by muse, mutect2, varscan2
- ST7L | c.1520dup p.E508Gfs*28 | Frame Shift Ins (INS) | VAF 105/331 reads (32%) | catalogued as rs1163874186; called by mutect2, pindel, varscan2
- STAMBPL1 | c.1214dup p.F407Lfs*55 | Frame Shift Ins (INS) | VAF 91/352 reads (26%) | catalogued as rs752994755; called by mutect2, varscan2
- STARD10 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 73/170 reads (43%) | catalogued as COSV58324951; called by muse, mutect2, varscan2
- STK3 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 264/702 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.151); catalogued as COSV69222833; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 41/88 reads (47%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM4 | c.6479G>A p.R2160H | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs144957611, COSV53609764; called by muse, mutect2, varscan2
- TESC | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1326703975, COSV58811396; called by muse, mutect2, varscan2
- TET2 | c.1842del p.L615Sfs*24 | Frame Shift Del (DEL) | VAF 24/148 reads (16%) | catalogued as rs763386429; called by mutect2, pindel, varscan2
- THEMIS | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV100965627, COSV64070330; called by muse, mutect2, varscan2
- THOP1 | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs368086026; called by muse, mutect2, varscan2
- TMBIM1 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV50310886; called by muse, mutect2, varscan2
- TMEM216 | c.359T>C p.M120T (on ENST00000515837 / NM_001173990.3; = p.M59T on NM_016499.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/380 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs367737418; called by muse, mutect2, varscan2
- TOP2B | c.2071G>A p.E691K (on ENST00000264331 / NM_001330700.2; = p.E686K on NM_001068.3) | Missense Mutation (SNP) | VAF 128/354 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV51970500; called by muse, mutect2, varscan2
- TPR | c.1697G>T p.R566I | Missense Mutation (SNP) | VAF 36/515 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs755724315, COSV100823703; called by muse, mutect2
- TRAF2 | c.26del p.P9Lfs*77 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs748531430; called by mutect2, pindel, varscan2
- TRIM32 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.439); catalogued as rs11556350, COSV57758444; called by muse, mutect2, varscan2
- TRIP10 | c.1490C>T p.P497L (on ENST00000313244 / NM_001288962.2; = p.P441L on NM_004240.4) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs556672884, COSV55585442; called by muse, mutect2, varscan2
- TRMT10C | c.393del p.K131Nfs*3 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs760928888; called by mutect2, varscan2
- TRO | c.4174A>T p.T1392S | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.365); catalogued as COSV51499855; called by muse, mutect2, varscan2
- TSEN15 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 283/821 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV62294186; called by muse, mutect2, varscan2
- TTN | c.85993G>A p.G28665R (on ENST00000591111; = p.G21241R on NM_003319.4) | Missense Mutation (SNP) | VAF 156/388 reads (40%) | PolyPhen probably damaging (1); catalogued as rs267599029, COSV100626139, COSV59890227; called by muse, mutect2, varscan2
- TTN | c.20600A>G p.N6867S (on ENST00000591111; = p.N5940S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/370 reads (4%) | PolyPhen benign (0.033); catalogued as COSV100598980; called by muse, mutect2
- TUBB4B | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61116146; called by muse, mutect2, varscan2
- UBA1 | c.1318A>G p.T440A | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV60112125; called by muse, mutect2, varscan2
- USP25 | c.2408G>A p.R803H | Missense Mutation (SNP) | VAF 84/245 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1426144494, COSV53482973; called by muse, mutect2, varscan2
- VPS35 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.265); catalogued as rs143688112, COSV54477932; called by muse, mutect2, varscan2
- WDR45 | c.422G>A p.R141Q (on ENST00000376372 / NM_001029896.2; = p.R142Q on NM_007075.3) | Missense Mutation (SNP) | VAF 168/465 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as COSV59875798; called by muse, mutect2, varscan2
- WDR59 | c.1802G>A p.S601N | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs1270342801, COSV50934400; called by muse, mutect2, varscan2
- WFIKKN1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as rs1292603263, COSV50193200; called by muse, mutect2, varscan2
- WIPF1 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs760461657, COSV55811095; called by muse, mutect2, varscan2
- WNK2 | c.1867A>G p.T623A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs766123567, COSV52937693; called by muse, mutect2, varscan2
- WTIP | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1455405621, COSV99542533; called by muse, mutect2, varscan2
- XPO4 | c.2645G>A p.C882Y | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.471); catalogued as COSV99688176; called by muse, mutect2, varscan2
- XPO7 | c.1662del p.F554Lfs*29 | Frame Shift Del (DEL) | VAF 21/206 reads (10%) | catalogued as rs35044426; called by mutect2, pindel, varscan2
- ZAN | c.4187G>A p.C1396Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61807435; called by muse, mutect2, varscan2
- ZBED9 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 25/386 reads (6%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV101509151; called by muse, mutect2
- ZBTB43 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV65094616; called by muse, mutect2, varscan2
- ZFC3H1 | c.2902C>T p.R968W | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749673445, COSV66431505; called by muse, mutect2, varscan2
- ZNF300 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs771864193, COSV51032314; called by muse, mutect2
- ZNF333 | c.1428G>T p.K476N | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV52885465, COSV52885931; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF570 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs544061459, COSV57578678; called by muse, mutect2, varscan2
- ZNF607 | c.1938G>A p.M646I | Missense Mutation (SNP) | VAF 95/276 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV67696595; called by muse, mutect2, varscan2
- ZNF780A | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 24/538 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.347); catalogued as rs759515065, COSV100574991; called by muse, mutect2
- ZNF816 | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 82/450 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs1403866840, COSV54410883; called by muse, mutect2, varscan2
- ALDH1A1 | c.1497_1499del p.K499del | In Frame Del (DEL) | VAF 198/554 reads (36%) | called by pindel, varscan2
- ANKFN1 | c.258del p.K86Nfs*22 | Frame Shift Del (DEL) | VAF 32/274 reads (12%) | called by mutect2, pindel, varscan2
- ASAP2 | c.2357del p.P786Rfs*25 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- B4GALNT3 | c.1638del p.R548Gfs*15 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- BBX | c.2088dup p.F697Ifs*8 | Frame Shift Ins (INS) | VAF 58/160 reads (36%) | called by mutect2, varscan2
- C2CD3 | c.1687dup p.S563Kfs*8 | Frame Shift Ins (INS) | VAF 138/386 reads (36%) | called by mutect2, varscan2
- CCDC93 | c.250del p.I84* | Frame Shift Del (DEL) | VAF 73/214 reads (34%) | called by mutect2, pindel, varscan2
- COL2A1 | c.509del p.P170Lfs*29 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.4754del p.P1585Qfs*18 (on ENST00000651564; = p.P1538Qfs*18 on NM_015692.5) | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- CTC1 | c.2249del p.P750Qfs*71 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- CUL9 | c.2668del p.T890Pfs*4 | Frame Shift Del (DEL) | VAF 108/334 reads (32%) | called by mutect2, pindel, varscan2
- DHX29 | c.671dup p.N224Kfs*15 | Frame Shift Ins (INS) | VAF 108/356 reads (30%) | called by mutect2, varscan2
- DST | c.8700del p.A2901Qfs*3 | Frame Shift Del (DEL) | VAF 68/194 reads (35%) | called by mutect2, pindel, varscan2
- E4F1 | c.866_867del p.K289Rfs*79 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- ENTPD5 | c.854del p.G285Vfs*2 | Frame Shift Del (DEL) | VAF 98/351 reads (28%) | called by mutect2, pindel, varscan2
- FAM13B | c.2346del p.F782Lfs*18 | Frame Shift Del (DEL) | VAF 211/645 reads (33%) | called by mutect2, pindel, varscan2
- FYB2 | c.1851del p.E618Rfs*24 | Frame Shift Del (DEL) | VAF 164/435 reads (38%) | called by mutect2, varscan2
- GABRG3 | c.294del p.F98Lfs*16 | Frame Shift Del (DEL) | VAF 71/228 reads (31%) | called by mutect2, pindel, varscan2
- GOLM1 | c.1153dup p.R385Kfs*8 | Frame Shift Ins (INS) | VAF 200/602 reads (33%) | called by mutect2, pindel, varscan2
- HERC2 | c.11900dup p.I3968Hfs*2 | Frame Shift Ins (INS) | VAF 55/154 reads (36%) | called by mutect2, pindel, varscan2
- HERC2 | c.8668del p.I2890Lfs*3 | Frame Shift Del (DEL) | VAF 60/150 reads (40%) | called by mutect2, pindel, varscan2
- IFNA14 | c.385del p.V129Wfs*6 | Frame Shift Del (DEL) | VAF 150/412 reads (36%) | called by mutect2, varscan2
- IGHV4-39 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGLV3-9 | c.185del p.P62Lfs*30 | Frame Shift Del (DEL) | VAF 45/154 reads (29%) | called by mutect2, pindel, varscan2
- KMT2D | c.8792del p.P2931Hfs*12 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- LAMA2 | c.4939dup p.M1647Nfs*23 | Frame Shift Ins (INS) | VAF 53/189 reads (28%) | called by mutect2, pindel, varscan2
- LMF1 | c.685del p.D229Tfs*83 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- LTB4R2 | c.1133del p.G378Vfs*47 (on ENST00000528054; = p.G347Vfs*47 on NM_019839.5) | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- LTK | c.2041del p.D681Tfs*76 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | called by mutect2, pindel, varscan2
- METTL25 | c.724del p.M242Wfs*44 | Frame Shift Del (DEL) | VAF 95/276 reads (34%) | called by mutect2, pindel, varscan2
- MORC1 | c.264del p.K88Nfs*6 | Frame Shift Del (DEL) | VAF 136/487 reads (28%) | called by mutect2, pindel, varscan2
- NRXN2 | c.4521del p.T1508Rfs*58 | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | called by mutect2, pindel, varscan2
- OR10G2 | c.253_256delinsTGAA p.L85_L86delins* | Nonsense Mutation (ONP) | VAF 20/103 reads (19%) | called by pindel, varscan2*
- OSBP | c.867del p.K289Nfs*62 | Frame Shift Del (DEL) | VAF 117/365 reads (32%) | called by mutect2, pindel, varscan2
- PKM | c.1124_1125del p.V375Afs*9 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by pindel, varscan2
- PPP2R1B | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 14/427 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTEN | c.867dup p.V290Sfs*8 | Frame Shift Ins (INS) | VAF 88/358 reads (25%) | called by pindel, varscan2
- RALGAPB | c.1142del p.P381Hfs*11 | Frame Shift Del (DEL) | VAF 168/531 reads (32%) | called by mutect2, pindel, varscan2
- RMDN3 | c.217dup p.A73Gfs*78 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- SEMA3E | c.1960del p.C654Afs*4 | Frame Shift Del (DEL) | VAF 127/398 reads (32%) | called by mutect2, pindel, varscan2
- SETD2 | c.4187del p.N1396Mfs*16 | Frame Shift Del (DEL) | VAF 131/470 reads (28%) | called by mutect2, pindel, varscan2
- SHROOM1 | c.1476del p.T493Qfs*32 | Frame Shift Del (DEL) | VAF 55/414 reads (13%) | called by pindel, varscan2
- SIN3B | c.1658del p.P553Rfs*19 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- SLC28A3 | c.534_536del p.W178_S179delinsC | In Frame Del (DEL) | VAF 76/213 reads (36%) | called by mutect2, pindel, varscan2
- SLC2A5 | c.1463del p.K488Rfs*4 | Frame Shift Del (DEL) | VAF 42/144 reads (29%) | called by mutect2, pindel, varscan2
- SLC38A6 | c.639del p.K213Nfs*8 | Frame Shift Del (DEL) | VAF 77/245 reads (31%) | called by mutect2, pindel, varscan2
- SLC40A1 | c.144_145del p.F49Sfs*32 | Frame Shift Del (DEL) | VAF 24/222 reads (11%) | called by pindel, varscan2
- SOCS3 | c.483del p.R162Efs*17 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- SPATA31D1 | c.528del p.S177Qfs*8 | Frame Shift Del (DEL) | VAF 191/613 reads (31%) | called by mutect2, pindel, varscan2
- TAF15 | c.174_175del p.Q60Vfs*11 (on ENST00000605844 / NM_139215.3; = p.S59Lfs*9 on NM_003487.4) | Frame Shift Del (DEL) | VAF 57/360 reads (16%) | called by mutect2, pindel, varscan2
- TGFBRAP1 | c.1755del p.K585Nfs*7 | Frame Shift Del (DEL) | VAF 320/942 reads (34%) | called by mutect2, pindel, varscan2
- TMEM168 | c.690del p.F230Lfs*4 | Frame Shift Del (DEL) | VAF 84/229 reads (37%) | called by mutect2, pindel, varscan2
- TNMD | c.320del p.N107Tfs*22 | Frame Shift Del (DEL) | VAF 140/364 reads (38%) | called by mutect2, varscan2
- USP10 | c.1886del p.F629Sfs*41 | Frame Shift Del (DEL) | VAF 87/263 reads (33%) | called by mutect2, pindel, varscan2
- VIRMA | c.2163del p.F721Lfs*11 | Frame Shift Del (DEL) | VAF 46/118 reads (39%) | called by mutect2, varscan2
- ZNF644 | c.1706dup p.T570Dfs*20 | Frame Shift Ins (INS) | VAF 56/146 reads (38%) | called by mutect2, varscan2
- AHNAK2 | c.14733G>A p.L4911= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV60912208; called by muse, mutect2, varscan2
- ALB | c.939C>T p.C313= | Silent (SNP) | VAF 128/334 reads (38%) | catalogued as COSV55736986; called by muse, mutect2, varscan2
- ALOX12B | c.1920C>T p.D640= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as COSV59872144; called by muse, mutect2, varscan2
- AP1M1 | c.337C>T p.L113= | Silent (SNP) | VAF 73/168 reads (43%) | catalogued as COSV52225869; called by muse, mutect2, varscan2
- ARMC4 | c.520C>T p.L174= | Silent (SNP) | VAF 138/344 reads (40%) | catalogued as COSV53464100; called by muse, mutect2, varscan2
- ASMTL | c.1215G>A p.A405= | Silent (SNP) | VAF 200/558 reads (36%) | catalogued as rs371234749, COSV67243296; called by muse, mutect2, varscan2
- ATXN2 | c.3285C>T p.Y1095= (on ENST00000550104; = p.Y935= on NM_002973.4) | Silent (SNP) | VAF 90/242 reads (37%) | catalogued as rs773866011, COSV66482357; called by muse, mutect2, varscan2
- AUTS2 | c.1695C>T p.D565= | Silent (SNP) | VAF 32/428 reads (7%) | catalogued as COSV100715395; called by muse, mutect2
- BMP7 | c.1062C>T p.Y354= | Silent (SNP) | VAF 63/166 reads (38%) | catalogued as rs771059650, COSV67780220; called by muse, mutect2, varscan2
- C11orf16 | c.372C>T p.V124= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs750137546, COSV58166840; called by muse, mutect2, varscan2
- C12orf29 | c.156A>G p.A52= | Silent (SNP) | VAF 116/304 reads (38%) | catalogued as COSV63554616; called by muse, mutect2, varscan2
- CACNB1 | c.1581A>C p.S527= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV59998517; called by muse, mutect2, varscan2
- CADPS2 | c.3055C>T p.L1019= | Silent (SNP) | VAF 93/265 reads (35%) | catalogued as COSV57357170; called by muse, mutect2, varscan2
- CDK5 | c.201T>C p.H67= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV52521330; called by muse, mutect2, varscan2
- CHN1 | c.447A>T p.T149= | Silent (SNP) | VAF 189/554 reads (34%) | catalogued as COSV69295903; called by muse, mutect2, varscan2
- CLIC3 | c.285G>A p.A95= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs909049334, COSV100860340; called by muse, mutect2, varscan2
- COLEC11 | c.72T>C p.H24= | Silent (SNP) | VAF 64/192 reads (33%) | catalogued as COSV52592808, COSV52598096; called by muse, mutect2, varscan2
- CPNE9 | c.187C>T p.L63= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as COSV56004218; called by muse, mutect2, varscan2
- CSMD1 | c.1761C>T p.F587= (on ENST00000520002; = p.F586= on NM_033225.6) | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100144943; called by muse, mutect2, varscan2
- CYP24A1 | c.963A>C p.T321= | Silent (SNP) | VAF 10/199 reads (5%) | catalogued as COSV99398113; called by muse, mutect2
- DNAI2 | c.1575G>A p.A525= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs767324607, COSV56757472; called by muse, mutect2, varscan2
- DOCK7 | c.1605T>C p.P535= | Silent (SNP) | VAF 102/329 reads (31%) | catalogued as COSV52001402; called by muse, mutect2, varscan2
- ELF4 | c.315C>T p.S105= | Silent (SNP) | VAF 145/444 reads (33%) | catalogued as rs753928588, COSV57452110; called by muse, mutect2, varscan2
- ELOA3C | c.636C>T p.G212= | Silent (SNP) | VAF 29/592 reads (5%) | catalogued as rs748015210; called by muse, mutect2
- ENO1 | c.402C>T p.I134= | Silent (SNP) | VAF 50/76 reads (66%) | catalogued as rs369611743; called by muse, mutect2, varscan2
- ETNK1 | c.198C>T p.Y66= | Silent (SNP) | VAF 67/187 reads (36%) | catalogued as rs370696559; called by muse, mutect2, varscan2
- ETV6 | c.432G>A p.P144= | Silent (SNP) | VAF 155/489 reads (32%) | catalogued as rs769260605, COSV67149094; called by muse, mutect2, varscan2
- F10 | c.1266G>A p.P422= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs528688585, COSV65021320; called by muse, mutect2, varscan2
- FAM126B | c.1059A>G p.S353= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as COSV99627462; called by muse, mutect2
- FAT4 | c.1332C>T p.Y444= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV67883786; called by muse, mutect2, varscan2
- FLCN | c.837C>T p.T279= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs751877389, COSV53258483; called by muse, mutect2, varscan2
- GAA | c.2700G>A p.Q900= | Silent (SNP) | VAF 6/154 reads (4%) | catalogued as rs1490464728, COSV100163002; called by muse, mutect2
- GAD2 | c.292C>T p.L98= | Silent (SNP) | VAF 95/235 reads (40%) | catalogued as COSV52154630; called by muse, mutect2, varscan2
- GCNA | c.765C>T p.P255= | Silent (SNP) | VAF 42/198 reads (21%) | catalogued as rs370469989, COSV65466359; called by muse, mutect2, varscan2
- GEMIN8 | c.660G>A p.Q220= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV60550306; called by muse, mutect2, varscan2
- GINS3 | c.294T>C p.T98= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV58919578; called by muse, mutect2, varscan2
- GUSB | c.423G>A p.E141= | Silent (SNP) | VAF 11/234 reads (5%) | catalogued as COSV100512522, COSV100512606; called by muse, mutect2
- HEMK1 | c.246G>A p.P82= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as rs774145570, COSV51750245; called by muse, mutect2, varscan2
- HGF | c.1050A>C p.R350= | Silent (SNP) | VAF 120/313 reads (38%) | catalogued as COSV55947425; called by muse, mutect2, varscan2
- HIPK3 | c.705C>A p.A235= | Silent (SNP) | VAF 27/175 reads (15%) | catalogued as COSV57561776; called by muse, mutect2, varscan2
- HSF2 | c.882G>A p.E294= | Silent (SNP) | VAF 14/177 reads (8%) | catalogued as COSV100869652; called by muse, mutect2
- HSPA2 | c.516C>T p.R172= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV55969220; called by muse, mutect2, varscan2
- ILDR1 | c.111G>A p.L37= | Silent (SNP) | VAF 52/272 reads (19%) | catalogued as COSV56549226; called by muse, mutect2, varscan2
- ITGA5 | c.1809G>A p.P603= | Silent (SNP) | VAF 156/380 reads (41%) | catalogued as rs910126941, COSV53215910; called by muse, mutect2, varscan2
- JADE1 | c.2298C>T p.H766= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs773444622, COSV56905148; called by muse, mutect2, varscan2
- JMY | c.2577A>G p.S859= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV68660375; called by muse, mutect2, varscan2
- KCNH6 | c.1168C>T p.L390= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs758121601, COSV59002009; called by muse, mutect2, varscan2
- LAS1L | c.492C>T p.P164= | Silent (SNP) | VAF 183/559 reads (33%) | catalogued as rs752812649, COSV56706872; called by muse, mutect2, varscan2
- LIG3 | c.1293C>T p.D431= | Silent (SNP) | VAF 74/209 reads (35%) | catalogued as rs562460258, COSV52006581; called by muse, mutect2, varscan2
- MAN2C1 | c.2365C>T p.L789= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV51227489; called by muse, mutect2, varscan2
- MCF2L2 | c.3237C>A p.T1079= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV61051630; called by muse, mutect2, varscan2
- MTUS1 | c.3132T>C p.H1044= (on ENST00000262102 / NM_001363061.1; = p.H210= on NM_020749.4) | Silent (SNP) | VAF 122/356 reads (34%) | catalogued as COSV50553569; called by muse, mutect2, varscan2
- MXRA5 | c.4032T>C p.T1344= | Silent (SNP) | VAF 149/421 reads (35%) | catalogued as COSV54230733; called by muse, mutect2, varscan2
- MYH9 | c.5124C>T p.D1708= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs369135992; called by muse, mutect2, varscan2
- MYO15A | c.2880G>A p.P960= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs762692576, COSV52754752; called by muse, mutect2, varscan2
- MYO16 | c.4878C>T p.A1626= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV62748358; called by muse, mutect2, varscan2
- NAV2 | c.2496C>T p.N832= (on ENST00000396087 / NM_001244963.2; = p.N809= on NM_145117.5) | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs754533487, COSV62319532; called by muse, mutect2, varscan2
- NES | c.4404C>T p.P1468= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV63960696; called by muse, mutect2, varscan2
- NEXMIF | c.3636T>C p.P1212= | Silent (SNP) | VAF 16/500 reads (3%) | catalogued as COSV99279963; called by muse, mutect2
- NFATC3 | c.2814G>A p.P938= | Silent (SNP) | VAF 112/295 reads (38%) | catalogued as rs768117476, COSV60472533; called by muse, mutect2, varscan2
- NKAP | c.639C>T p.S213= | Silent (SNP) | VAF 231/631 reads (37%) | catalogued as rs771673500, COSV65056055; called by muse, mutect2, varscan2
- NMUR2 | c.465A>G p.K155= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV99676687; called by muse, mutect2
- NPAS3 | c.822C>T p.R274= (on ENST00000356141 / NM_001164749.2; = p.R242= on NM_022123.3) | Silent (SNP) | VAF 129/320 reads (40%) | catalogued as rs368561940; called by muse, mutect2, varscan2
- NRM | c.546C>T p.A182= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99223582; called by muse, varscan2
- OR13C8 | c.246T>C p.L82= | Silent (SNP) | VAF 34/709 reads (5%) | catalogued as COSV100622945; called by muse, mutect2
- OR9I1 | c.567C>T p.C189= | Silent (SNP) | VAF 72/237 reads (30%) | catalogued as COSV56925743; called by muse, mutect2, varscan2
- PAPSS2 | c.309T>C p.I103= | Silent (SNP) | VAF 68/179 reads (38%) | catalogued as COSV63263020; called by muse, mutect2, varscan2
- PCBP3 | c.117A>G p.E39= | Silent (SNP) | VAF 59/144 reads (41%) | catalogued as COSV68407489; called by muse, mutect2, varscan2
- PCF11 | c.2526A>G p.G842= | Silent (SNP) | VAF 116/318 reads (36%) | catalogued as COSV53535130; called by muse, mutect2
- PHLPP2 | c.2079G>A p.L693= | Silent (SNP) | VAF 133/740 reads (18%) | catalogued as rs1567613510, COSV62423740; called by muse, mutect2, varscan2
- PNPLA7 | c.2961C>T p.A987= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs550255849, COSV52997059; called by muse, mutect2, varscan2
- POTEF | c.2394C>T p.P798= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as rs375441303; called by muse, varscan2
- PPP1R13B | c.2346C>T p.P782= | Silent (SNP) | VAF 99/219 reads (45%) | catalogued as rs764606468, COSV52450335; called by muse, mutect2, varscan2
- PRPF38A | c.690C>T p.R230= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV57122124; called by muse, mutect2, varscan2
- PSMD12 | c.195T>C p.R65= | Silent (SNP) | VAF 16/352 reads (5%) | catalogued as COSV100635291; called by muse, mutect2
- RAB11FIP5 | c.1438C>A p.R480= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV50248520, COSV50250273; called by muse, mutect2, varscan2
- RFX1 | c.2172C>T p.H724= | Silent (SNP) | VAF 35/251 reads (14%) | catalogued as rs143289931; called by muse, mutect2, varscan2
- RPRD1A | c.762C>T p.A254= | Silent (SNP) | VAF 9/280 reads (3%) | catalogued as COSV100036154; called by muse, mutect2
- RTP1 | c.573C>T p.C191= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1034641198, COSV56618123; called by muse, mutect2, varscan2
- RUFY1 | c.2076C>T p.C692= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs745394269, COSV60159243, COSV60161704; called by muse, mutect2, varscan2
- SALL2 | c.720C>T p.P240= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as rs1393390215, COSV58102665; called by muse, mutect2, varscan2
- SENP1 | c.924A>G p.S308= | Silent (SNP) | VAF 127/346 reads (37%) | catalogued as COSV50287033; called by muse, mutect2, varscan2
- SF3B1 | c.429T>C p.P143= | Silent (SNP) | VAF 154/412 reads (37%) | catalogued as rs952793246, COSV59211442; called by muse, mutect2, varscan2
- SHPRH | c.1459C>T p.L487= | Silent (SNP) | VAF 164/420 reads (39%) | catalogued as COSV51607165; called by muse, mutect2, varscan2
- SLC39A5 | c.273C>T p.D91= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV57191236; called by muse, mutect2, varscan2
- SPATA20 | c.2163C>T p.C721= (on ENST00000356488 / NM_001258372.1; = p.C737= on NM_022827.4) | Silent (SNP) | VAF 112/283 reads (40%) | catalogued as rs780672548, COSV50065985; called by muse, mutect2, varscan2
- SPIC | c.372G>A p.P124= | Silent (SNP) | VAF 78/200 reads (39%) | catalogued as COSV54690594; called by muse, mutect2, varscan2
- SPOUT1 | c.561C>T p.S187= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as rs144735167; called by muse, mutect2, varscan2
- STING1 | c.480A>G p.A160= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV58172377; called by muse, mutect2, varscan2
- SUN1 | c.1812C>T p.S604= (on ENST00000405266 / NM_001367651.1; = p.S484= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs199966268, COSV67448406; called by muse, mutect2, varscan2
- SYCE1 | c.642C>T p.C214= (on ENST00000343131 / NM_001143764.3; = p.C178= on NM_130784.3) | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV58216598; called by muse, mutect2, varscan2
- SYDE1 | c.1695C>T p.R565= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs1471583755, COSV54618764; called by muse, mutect2, varscan2
- TBC1D31 | c.1959G>A p.T653= | Silent (SNP) | VAF 131/336 reads (39%) | catalogued as rs760998409, COSV54865070; called by muse, mutect2, varscan2
- TEX11 | c.1026T>C p.A342= (on ENST00000344304; = p.A327= on NM_031276.3) | Silent (SNP) | VAF 36/487 reads (7%) | catalogued as COSV100721428; called by muse, mutect2
- TGFBR2 | c.1434G>A p.V478= | Silent (SNP) | VAF 84/195 reads (43%) | catalogued as COSV55446944; called by muse, mutect2, varscan2
- TMC4 | c.129G>A p.L43= (on ENST00000617472 / NM_001145303.3; = p.L37= on NM_144686.4) | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV55475083; called by muse, mutect2, varscan2
- TMEM267 | c.420A>G p.S140= | Silent (SNP) | VAF 57/161 reads (35%) | catalogued as COSV67992566; called by muse, mutect2, varscan2
- TNS2 | c.1677C>T p.R559= (on ENST00000314250 / NM_170754.4; = p.R569= on NM_015319.2) | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs539615970, COSV58576340; called by muse, mutect2, varscan2
- TNS3 | c.237G>A p.P79= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs199837393; called by muse, mutect2
- TPPP | c.357G>A p.A119= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs777737792, COSV62191704; called by muse, mutect2, varscan2
- UBE3C | c.988T>C p.L330= | Silent (SNP) | VAF 49/231 reads (21%) | catalogued as COSV61952399; called by muse, mutect2, varscan2
- UNC93B1 | c.759G>A p.T253= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as rs1342020868, COSV57098566; called by muse, mutect2, varscan2
- USPL1 | c.78C>T p.H26= | Silent (SNP) | VAF 137/412 reads (33%) | catalogued as rs571002845, COSV54999361; called by muse, mutect2, varscan2
- VCPIP1 | c.2643A>G p.S881= | Silent (SNP) | VAF 94/240 reads (39%) | catalogued as COSV60046575; called by muse, mutect2, varscan2
- VPS13D | c.3354G>A p.T1118= | Silent (SNP) | VAF 96/135 reads (71%) | catalogued as rs755480816, COSV50621416; called by muse, mutect2, varscan2
- WASHC5 | c.969C>T p.V323= | Silent (SNP) | VAF 183/477 reads (38%) | catalogued as COSV59195423, COSV59196598; called by muse, mutect2, varscan2
- YWHAG | c.597C>T p.T199= | Silent (SNP) | VAF 79/229 reads (34%) | catalogued as rs771197922, COSV56900573; called by muse, mutect2, varscan2
- ZMAT3 | c.123G>A p.Q41= | Silent (SNP) | VAF 123/325 reads (38%) | catalogued as COSV60992730; called by muse, mutect2, varscan2
- ZNF41 | c.168A>G p.T56= | Silent (SNP) | VAF 107/263 reads (41%) | catalogued as COSV57441953; called by muse, mutect2, varscan2
- CTSL3P | n.220G>A | RNA (SNP) | VAF 162/440 reads (37%) | catalogued as rs756482365; called by muse, mutect2, varscan2
- DIO3 | chr14:101560365 G>A | 5'Flank (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- HDAC2 | c.-189A>G | 5'UTR (SNP) | VAF 10/22 reads (45%) | catalogued as rs1016833113, COSV64037794; called by muse, mutect2, varscan2
- HEXD | c.1062-40del | Intron (DEL) | VAF 31/91 reads (34%) | catalogued as rs1567898177; called by mutect2, pindel, varscan2
- MIR124-3 | n.70G>A | RNA (SNP) | VAF 6/21 reads (29%) | catalogued as rs749909250; called by muse, mutect2, varscan2
- MYB | c.1203+1129G>A | Intron (SNP) | VAF 80/195 reads (41%) | catalogued as COSV57197286; called by muse, mutect2, varscan2
- NCAM1 | c.1825+1140G>A | Intron (SNP) | VAF 36/908 reads (4%) | called by muse, mutect2
- SYNE1 | c.24977-1777C>T | Intron (SNP) | VAF 162/421 reads (38%) | catalogued as rs761266231, COSV54949322; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
